Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A7DV, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A7DV-01A (Primary Tumor).

[page 1 of 2]
TSS Patient ID:

Surgical Date:

Gross Description: 1. Lymph node iliac commune, max. dim. 1.5cm with metastasis of urothelial carcinoma, poor differentiated, (high-grade)

2. Piece of cystoprostatectomy presenting the urinary bladder with cavity occupied by sizable tumor, vegetative, developed on trigone level, intramural evolution, peri-OUS and invasive in the whole wall. Histopathological aspect of infiltrative urothelial cell carcinoma, papillary, poorly differentiated, G3, with giant cells, tumoural groups with sarcomatoid aspects, necrosis, ulceration, intramural evolution and invasion of the entire bladder wall, prostate and seminal vesicles; stpT4. Numerous intramural tumoral emboli.

3. Right ureter without malign elements.

4. Right iliac intern, extern and obturator adenopathic block of 5cm with metastasis of low differentiated carcinoma (high-grade).

5. Right para-rectal adenopathy, node max 1.0 cm with metastasis of urothelial carcinoma (high-grade).

6. Left iliac intern, extern and obturator adenopathic block of 4cm with metastasis of low differentiated carcinoma (high-grade).

7. Left kidney presenting pielo-caliceal cavities with mucosa covered by fibrinous-hematic clots, medular/cortical contrast preserved. Histopatologic aspect of focal non-specific chronic nephritis. Renal pelvis and ureter with hematic subepithelial suffusions. Mid and distal ureter with large lumen, chorion edema.

Microscopic Description: see above

Diagnosis Details: CONCLUSION:

Infiltrative urothelial cell carcinoma of the bladder, papillary with giant cells and sarcomatoid aspects, poorly differentiated, G3, (high-grade), stpT4, pN3, pMx (stage IV). Intramural tumoral emboli. Code 8130/3

Pielonephritis chronic, non-specific in focuses

Comments:

Formatted Path Reports: BLADDER TISSUE CHECKLIST

Specimen type: Radical cystectomy

Tumor site: Bladder

ICD-O-3
Carcinoma papillary transitional cell
8130/3
Site ^{C67.9} Bladder NOS C67.9
path Bladder trigone C67.0
7/14/13

[page 2 of 2]
Tumor size: Not specified

Tumor features: Ulcerated

Histologic type: Transitional cell carcinoma, papillary

Histologic grade: Poorly differentiated

Tumor extent: Invades to prostate

Lymph nodes: 4/4 positive for metastasis (Regional 4/4)

Lymphatic invasion: Present

Venous invasion: Present

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Criteria	W 8/21/13	Yes	No
Case is (check one) CLINICAL / DISCREPANT			✓

Source: NCI Genomic Data Commons file 5b50e556-bc36-4a8e-813e-cff5a210f136 (TCGA-E7-A7DV.7226D91A-DF25-4FAE-B300-5E33F29C0E61.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).